Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A03M, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A03M-01B (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:
Left breast carcinoma.

Specimens Submitted:
1: SP: Left breast

DIAGNOSIS:

- 1) BREAST, LEFT; TOTAL MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, POORLY DIFFERENTIATED, HISTOLOGIC GRADE III/III, NUCLEAR GRADE III/III, MEASURING 1.7 CM MICROSCOPICALLY.
- THE TUMOR IS LOCATED IN THE UPPER OUTER QUADRANT.
- NO IN SITU COMPONENT IS IDENTIFIED.
- LYMPHOVASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE NIPPLE BY CARCINOMA.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE SURGICAL MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES AND FIBROCYSTIC CHANGES.

RESULTS OF THE IMMUNOHISTOCHEMICAL STAINS (ER, PR, HER-2/NEU) WILL BE REPORTED IN AN ADDENDUM.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:
Result

Special Stain
ER-C
PR-C
HER2-C
NEG CONT
IMM RECUT
NEG-HER2

Comment

1CD-0-3
carcinoma, infiltrating duct, NOS
8500/3
Site: breast, NOS C50.9

hw
10/21/11

** Continued on next page **

hw 10/21/11

[page 2 of 3]
Gross Description:

M.D.

1) The specimen is received fresh, labeled "Left breast ,stitch marks axillary tail" and consists of a breast measuring 19 x 14 x 5 cm with overlying skin ellipse measuring 9 x 2.5 cm. Situated centrally on the skin surface is an everted nipple measuring 1.5 x 1.5 cm and areola measuring 3 x 2.5 cm. A suture demarcates the axillary aspect. The posterior surface of the breast is inked black and the specimen is serially sectioned to reveal an ill-defined white tan area measuring 5 x 4 x 3 cm, located 0.4 from the deep margin in the upper outer quadrant. There is an adjacent ill-defined fibrous area measuring 6 x 5 x 4 cm The remaining breast tissue shows lobulated fibrofatty tissue. The axillary aspect is dissected to reveal no grossly identifiable lymph nodes. Representative sections of the mastectomy specimen are submitted.

Summary of sections:

N - nipple
NB - nipple base
S - skin
D - deep margin
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
H hemorrhagic area
T ill-defined area suspicious for tumor

Summary of Sections:

Part 1: SP: Left breast

Block	Sect.	Site	PCs
1		D	1
2		H	2
2		LIQ	2
2		LOQ	2
1		N	1
1		NB	1
1		S	1
5		T	5
2		UIQ	2
2		UOQ	2

Procedures/Addenda:

Addendum

** Continued on next page **

[page 3 of 3]
Date Ordered:
Date Complete:
Date Reported:

Status: Signed Out
By:

Page 3 of 3

Addendum Diagnosis

ADDENDUM

BREAST, LEFT; TOTAL MASTECTOMY:

THE INVASIVE CARCINOMA SHOWS THE FOLLOWING IMMUNOPHENOTYPE:

- ER: POSITIVE (70% NUCLEAR STAINING WITH MODERATE INTENSITY)
- PR: POSITIVE (60% NUCLEAR STAINING WITH MODERATE TO STRONG INTENSITY)
- HER-2/NEU (HERCEPTEST): STAINING INTENSITY OF 2+.

CONTROLS ARE SATISFACTORY.

MD

** End of Report **

Source: NCI Genomic Data Commons file 913d0738-f9ea-4613-9842-a3f31d40a366 (TCGA-AO-A03M.967287FE-7751-4A90-9465-0A1AD007061D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).